Somatic mutation profile of tumor specimen TCGA-VV-A86M-01A (aliquot TCGA-VV-A86M-01A-11D-A36O-08) from TCGA case TCGA-VV-A86M, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.8 years (13,453 days).
Specimen TCGA-VV-A86M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62078fbe-f2f9-4189-b870-67b0a8f6ef88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VV-A86M-10A (Blood Derived Normal), aliquot TCGA-VV-A86M-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63fb0ace-29a4-45d4-b1ed-d4b0471dca44

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/59 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DNAJA1 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs914592363, COSV100438595; called by muse, mutect2, varscan2
- MYO15A | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs1419468164, COSV99233950; called by muse, mutect2, varscan2
- PWWP3B | c.1229T>A p.I410K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV61798301; called by muse, mutect2, varscan2
- SEC63 | c.1834-1G>A p.X612_splice | Splice Site (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100938449; called by mutect2, varscan2
- WDR77 | c.716T>C p.L239P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1287202006, COSV99330932; called by muse, mutect2, varscan2
- ZNF165 | c.973T>C p.S325P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs866422641, COSV101056027; called by muse, mutect2, varscan2
- PHB | c.344del p.D115Vfs*25 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- ADD3 | c.1752C>G p.L584= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV99523619; called by muse, mutect2, varscan2
- ATRX | c.639A>C p.S213= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV100971255; called by muse, mutect2, varscan2
- SLC39A7 | c.222A>G p.G74= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs1487213798, COSV100807820; called by muse, mutect2, varscan2
